Somatic mutation profile of tumor specimen TCGA-61-2614-01A (aliquot TCGA-61-2614-01A-01W-1092-09) from TCGA case TCGA-61-2614, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 71.6 years (26,142 days).
Specimen TCGA-61-2614-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5101f347-3f49-4645-b7e3-fa722088b93c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-2614-10A (Blood Derived Normal), aliquot TCGA-61-2614-10A-01W-1092-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1802b8d9-50a0-4cb8-9cc7-26e4b73cd68c

The open-access MAF lists 56 somatic variants for this specimen: 46 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 9, Nonsense Mutation 4, Frame Shift Del 2, Translation Start Site 1, Splice Site 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.824G>A p.C275Y | Missense Mutation (SNP) | VAF 156/241 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS19 | c.1243G>A p.G415S | Missense Mutation (SNP) | VAF 39/275 reads (14%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.925); catalogued as COSV50737531, COSV50769344; called by muse, mutect2, varscan2
- AKAP6 | c.2895T>A p.D965E | Missense Mutation (SNP) | VAF 64/377 reads (17%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.991); catalogued as COSV99801997; called by muse, mutect2
- AL136295.1 | c.1973A>G p.N658S | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.872); catalogued as COSV55779095; called by muse, mutect2, varscan2
- ARNT2 | c.1463C>G p.S488C | Missense Mutation (SNP) | VAF 106/159 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV57583957, COSV57588994; called by muse, mutect2, varscan2
- ASB4 | c.128A>G p.D43G | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV57507822; called by muse, mutect2, varscan2
- CD163 | c.1670G>A p.C557Y | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63131520, COSV63138368; called by muse, mutect2, varscan2
- CLIP1 | c.1006-1G>C p.X336_splice | Splice Site (SNP) | VAF 6/42 reads (14%) | catalogued as COSV56800626; called by muse, mutect2, varscan2
- DBF4 | c.1750C>T p.R584* | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as rs144858770; called by muse, mutect2, varscan2
- DDA1 | c.87C>T p.N29= | Splice Region (SNP) | VAF 5/30 reads (17%) | catalogued as COSV63289602; called by muse, mutect2, varscan2
- DUSP12 | c.93G>C p.Q31H | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.11); catalogued as COSV63411264; called by muse, mutect2, varscan2
- E2F7 | c.1769C>T p.P590L | Missense Mutation (SNP) | VAF 39/242 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV59738968; called by muse, mutect2, varscan2
- EIF3L | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs765784918, COSV67739527; called by muse, mutect2, varscan2
- ELOVL3 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 36/109 reads (33%) | catalogued as COSV64174397; called by muse, mutect2, varscan2
- FIZ1 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 73/89 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV55607539, COSV99684515; called by muse, mutect2, varscan2
- FZD4 | c.1493C>G p.A498G | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as COSV72294327; called by muse, mutect2, varscan2
- GATAD2B | c.305A>G p.D102G | Missense Mutation (SNP) | VAF 327/398 reads (82%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as COSV64083888; called by muse, mutect2, varscan2
- GGN | c.1153G>T p.G385W | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99287531; called by muse, mutect2
- GHRHR | c.1110C>A p.F370L | Missense Mutation (SNP) | VAF 53/304 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as COSV58196195; called by muse, mutect2, varscan2
- IQGAP2 | c.1921G>C p.E641Q | Missense Mutation (SNP) | VAF 52/381 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV57171965, COSV57181795; called by muse, mutect2, varscan2
- IRF6 | c.134G>C p.R45P | Missense Mutation (SNP) | VAF 43/265 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM034818, COSV100883988, COSV65419171; called by muse, mutect2, varscan2
- ITSN2 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 37/234 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as COSV100743795; called by muse, mutect2, varscan2
- KARS1 | c.1084G>A p.V362M | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs780944129, COSV56691702; called by muse, mutect2, varscan2
- KCNA3 | c.326A>T p.N109I | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63901337; called by muse, mutect2, varscan2
- KLB | c.1513G>T p.E505* | Nonsense Mutation (SNP) | VAF 100/395 reads (25%) | catalogued as COSV57300925; called by muse, mutect2, varscan2
- LCE1C | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 174/206 reads (84%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.911); catalogued as rs780385036, COSV64218273; called by mutect2, varscan2
- LIG4 | c.1945C>T p.L649F | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.179); catalogued as COSV63596880; called by muse, mutect2, varscan2
- LILRA6 | c.1418G>C p.R473T | Missense Mutation (SNP) | VAF 440/938 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.805); catalogued as COSV54433738; called by muse, varscan2
- MACO1 | c.102C>A p.F34L | Missense Mutation (SNP) | VAF 179/254 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as COSV65476185; called by muse, mutect2, varscan2
- MAP2K4 | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62256611, COSV62260765; called by muse, mutect2, varscan2
- MFSD11 | c.1222T>C p.Y408H | Missense Mutation (SNP) | VAF 123/520 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as COSV60622773; called by muse, mutect2, varscan2
- MKRN3 | c.1406G>A p.R469Q | Missense Mutation (SNP) | VAF 106/232 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV58809514; called by muse, mutect2, varscan2
- NFAT5 | c.2102G>A p.S701N | Missense Mutation (SNP) | VAF 77/381 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs751187444, COSV63026661; called by muse, mutect2, varscan2
- OR10K2 | c.814G>T p.A272S | Missense Mutation (SNP) | VAF 74/412 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV59220982; called by muse, mutect2, varscan2
- PACSIN3 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs549826440, COSV54065754; called by muse, mutect2, varscan2
- PHACTR3 | c.374C>T p.T125I | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV100732798; called by muse, mutect2
- PITHD1 | c.562A>C p.N188H | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV55754766; called by muse, mutect2, varscan2
- PYGB | c.2030C>G p.T677R | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53815344, COSV99405231; called by muse, mutect2
- SEC23IP | c.1583T>A p.F528Y | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV64831276; called by muse, mutect2, varscan2
- SLC12A5 | c.154A>C p.I52L (on ENST00000454036 / NM_001134771.2; = p.I29L on NM_020708.5) | Missense Mutation (SNP) | VAF 143/271 reads (53%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV54791943; called by muse, mutect2, varscan2
- SLC6A14 | c.1725T>G p.I575M | Missense Mutation (SNP) | VAF 209/480 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.07); catalogued as COSV64140957; called by muse, mutect2, varscan2
- TP53TG5 | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 48/289 reads (17%) | catalogued as rs777445863, COSV65577133, COSV65577320, COSV65577985; called by muse, mutect2, varscan2
- WDR49 | c.383A>G p.N128S (on ENST00000308378 / NM_001366158.1; = p.N469S on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 93/543 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as rs977428406, COSV57706505; called by muse, mutect2, varscan2
- ZBED9 | c.1499G>C p.W500S | Missense Mutation (SNP) | VAF 47/253 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.987); catalogued as COSV71729324; called by muse, mutect2, varscan2
- CATSPER1 | c.527del p.G176Vfs*159 | Frame Shift Del (DEL) | VAF 15/84 reads (18%) | called by mutect2, pindel, varscan2
- STEAP2 | c.264_268del p.I89Cfs*21 | Frame Shift Del (DEL) | VAF 66/386 reads (17%) | called by pindel, varscan2
- CLEC14A | c.1410T>C p.D470= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV60562260; called by muse, mutect2, varscan2
- CLIP2 | c.342C>T p.D114= | Silent (SNP) | VAF 45/57 reads (79%) | catalogued as rs201025665, COSV56277329; called by muse, mutect2, varscan2
- COBLL1 | c.234A>G p.V78= (on ENST00000392717; = p.V40= on NM_014900.5) | Silent (SNP) | VAF 123/691 reads (18%) | catalogued as COSV52066447; called by muse, mutect2, varscan2
- GYG1 | c.954G>C p.S318= | Silent (SNP) | VAF 37/236 reads (16%) | catalogued as COSV56049301, COSV99936960; called by muse, mutect2, varscan2
- MKI67 | c.7092C>T p.L2364= | Silent (SNP) | VAF 226/870 reads (26%) | catalogued as COSV100896723; called by muse, mutect2
- PSMC6 | c.753T>C p.A251= (on ENST00000612399; = p.A237= on NM_002806.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/155 reads (6%) | catalogued as COSV101471204; called by muse, mutect2
- RGS20 | c.201C>T p.A67= | Silent (SNP) | VAF 6/65 reads (9%) | catalogued as COSV52021849; called by muse, mutect2
- SLC26A8 | c.1845T>C p.D615= | Silent (SNP) | VAF 52/322 reads (16%) | catalogued as COSV62885479; called by muse, mutect2, varscan2
- TTN | c.5430G>A p.R1810= (on ENST00000591111; = p.R1764= on NM_003319.4) | Silent (SNP) | VAF 67/125 reads (54%) | catalogued as rs1428790390, COSV59994152; called by muse, mutect2, varscan2
- KCNK10 | c.38-7226T>C | Intron (SNP) | VAF 122/542 reads (23%) | catalogued as COSV56643194; called by muse, mutect2, varscan2
